CCDI case PBCHDP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/06fdef57-75d1-46da-825a-566caeb1c298

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (183 days).

Biospecimens (3 samples)
- Sample 0DS28O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS29I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS29S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
